Somatic mutation profile of tumor specimen TCGA-EQ-5647-01A (aliquot TCGA-EQ-5647-01A-01D-1600-08) from TCGA case TCGA-EQ-5647, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IV; Tumor grade: G2; Age at diagnosis: 86.1 years (31,431 days).
Specimen TCGA-EQ-5647-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 070a32f9-f34a-42f0-890a-81154fc2e585.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EQ-5647-10A (Blood Derived Normal), aliquot TCGA-EQ-5647-10A-01D-1600-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4735d638-da71-415f-9809-eef1c44b1df7

The open-access MAF lists 82 somatic variants for this specimen: 60 protein-altering or splice-affecting, 21 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 57, Silent 21, Nonsense Mutation 3, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC9 | c.2474C>T p.A825V | Missense Mutation (SNP) | VAF 1027/1400 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs964127282, COSV53973119; called by muse, mutect2, varscan2
- ADAMTS14 | c.1894C>A p.H632N | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV64604841; called by muse, mutect2, varscan2
- ADAT1 | c.1168C>T p.R390* | Nonsense Mutation (SNP) | VAF 14/77 reads (18%) | catalogued as rs778703472, COSV57187830; called by muse, mutect2, varscan2
- AIMP2 | c.950A>C p.K317T | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.145); catalogued as COSV52241842; called by muse, mutect2, varscan2
- C2orf78 | c.1310C>T p.S437F | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.819); catalogued as COSV68518660; called by muse, mutect2, varscan2
- C3 | c.2085G>T p.E695D | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.655); catalogued as rs1388206754; called by muse, mutect2
- CCR1 | c.342C>A p.Y114* | Nonsense Mutation (SNP) | VAF 29/117 reads (25%) | catalogued as COSV56122717; called by muse, mutect2, varscan2
- CHST7 | c.528C>G p.D176E | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.185); catalogued as COSV52100848, COSV99332931; called by muse, mutect2, varscan2
- COL6A6 | c.210G>T p.Q70H | Missense Mutation (SNP) | VAF 34/125 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62032708; called by muse, mutect2, varscan2
- DCAF12L1 | c.782G>T p.S261I | Missense Mutation (SNP) | VAF 46/85 reads (54%) | SIFT tolerated (0.2); PolyPhen benign (0.025); catalogued as COSV64422454; called by muse, mutect2, varscan2
- DCC | c.1058C>A p.T353K | Missense Mutation (SNP) | VAF 206/360 reads (57%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV59122668; called by muse, mutect2, varscan2
- FAAP100 | c.695A>C p.D232A | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59884970, COSV59886876; called by muse, mutect2, varscan2
- FAM81B | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 45/151 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.233); catalogued as rs372676686; called by muse, mutect2, varscan2
- GATA3 | c.382G>A p.G128R | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.029); catalogued as COSV60520760, COSV60521164; called by muse, mutect2, varscan2
- H2AC11 | c.181G>A p.A61T | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.936); catalogued as COSV60362486; called by muse, mutect2, varscan2
- H2AC13 | c.203G>A p.G68D | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as rs1479345518; called by muse, mutect2, varscan2
- HNRNPH2 | c.874C>A p.H292N | Missense Mutation (SNP) | VAF 27/184 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV54510155; called by muse, mutect2, varscan2
- ICAM4 | c.467C>T p.T156M | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.94); catalogued as COSV53425036; called by muse, mutect2, varscan2
- IL13RA2 | c.1091G>A p.R364H | Missense Mutation (SNP) | VAF 22/153 reads (14%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs377188116, COSV54566530; called by muse, mutect2, varscan2
- KCNJ5 | c.1186G>T p.A396S | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as rs754816201, COSV57969097; called by muse, varscan2
- KLC2 | c.212G>A p.G71E | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57583672; called by muse, mutect2, varscan2
- LCE2A | c.278C>A p.S93Y | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.347); catalogued as COSV64227044; called by muse, mutect2, varscan2
- LHFPL4 | c.598C>T p.R200W | Missense Mutation (SNP) | VAF 43/107 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754454753, COSV55000962; called by muse, mutect2, varscan2
- LIG4 | c.1738C>G p.R580G | Missense Mutation (SNP) | VAF 28/157 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs104894418, CM014720, COSV63597683; called by muse, mutect2, varscan2
- MAP7D2 | c.280C>T p.R94* | Nonsense Mutation (SNP) | VAF 104/176 reads (59%) | catalogued as COSV65528045; called by muse, mutect2, varscan2
- MED12L | c.982A>T p.S328C | Missense Mutation (SNP) | VAF 30/168 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.579); catalogued as COSV56389978; called by muse, mutect2, varscan2
- MYH3 | c.4129G>A p.E1377K | Missense Mutation (SNP) | VAF 109/287 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV56868153; called by muse, mutect2, varscan2
- NEBL | c.2385A>T p.R795S | Missense Mutation (SNP) | VAF 44/140 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.219); catalogued as COSV65804799; called by muse, mutect2, varscan2
- NXPE4 | c.1578C>A p.H526Q (on ENST00000375478 / NM_001077639.2; = p.H242Q on NM_017678.3) | Missense Mutation (SNP) | VAF 51/109 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64944169; called by muse, mutect2, varscan2
- OR1J2 | c.309T>G p.F103L | Missense Mutation (SNP) | VAF 8/203 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.216); catalogued as rs1203974700, COSV58944151; called by muse, mutect2
- PAN3 | c.1202C>T p.T401M | Missense Mutation (SNP) | VAF 82/204 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1178592350, COSV56706097; called by muse, mutect2, varscan2
- PTPN12 | c.1924A>G p.T642A | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT tolerated, low confidence (0.95); PolyPhen benign (0); catalogued as COSV50367412; called by muse, mutect2, varscan2
- PTPN13 | c.509A>G p.K170R | Missense Mutation (SNP) | VAF 38/160 reads (24%) | SIFT tolerated (0.55); PolyPhen benign (0.115); catalogued as COSV57413378; called by muse, mutect2, varscan2
- PTPRB | c.3367G>A p.D1123N | Missense Mutation (SNP) | VAF 24/838 reads (3%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); catalogued as COSV54238260, COSV54248666; called by muse, mutect2
- PTPRR | c.1727T>G p.L576R | Missense Mutation (SNP) | VAF 18/555 reads (3%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as COSV51741278; called by muse, mutect2
- RGS20 | c.302G>A p.R101H | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.005); catalogued as COSV52020416; called by muse, mutect2, varscan2
- RNF145 | c.1715C>T p.P572L (on ENST00000424310 / NM_001199383.2; = p.P600L on NM_144726.2) | Missense Mutation (SNP) | VAF 34/117 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50869596; called by muse, mutect2, varscan2
- RUNX3 | c.854C>T p.S285L | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.945); catalogued as rs202187723, COSV58245045; called by muse, mutect2, varscan2
- SEC24C | c.1639G>A p.V547I | Missense Mutation (SNP) | VAF 38/92 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.578); catalogued as rs770672041, COSV59543915; called by muse, mutect2, varscan2
- SLC12A4 | c.1333C>T p.R445C | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs200784647; called by muse, mutect2, varscan2
- SLC26A8 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.003); catalogued as COSV62887028; called by muse, mutect2, varscan2
- TAF1D | c.736A>G p.S246G | Missense Mutation (SNP) | VAF 40/121 reads (33%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.023); catalogued as COSV60639563; called by muse, mutect2, varscan2
- TEX11 | c.2479C>T p.P827S (on ENST00000344304; = p.P812S on NM_031276.3) | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.503); catalogued as COSV60235644; called by muse, mutect2, varscan2
- TNF | c.398T>G p.L133R | Missense Mutation (SNP) | VAF 30/147 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV69305178; called by muse, mutect2, varscan2
- TSG101 | c.790A>G p.K264E | Missense Mutation (SNP) | VAF 162/527 reads (31%) | SIFT tolerated (0.55); PolyPhen benign (0.04); catalogued as COSV52649603, COSV52651835; called by muse, mutect2, varscan2
- TSHZ2 | c.2679G>A p.M893I | Missense Mutation (SNP) | VAF 408/2352 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV61590285; called by muse, varscan2
- TSHZ2 | c.2758G>A p.D920N | Missense Mutation (SNP) | VAF 330/2090 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61590290; called by muse, varscan2
- TTLL4 | c.1901A>G p.N634S | Missense Mutation (SNP) | VAF 81/233 reads (35%) | SIFT tolerated (0.54); PolyPhen benign (0.024); catalogued as COSV51438372; called by muse, mutect2, varscan2
- USH2A | c.4777A>G p.T1593A | Missense Mutation (SNP) | VAF 33/336 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.311); catalogued as COSV56408963; called by muse, mutect2, varscan2
- USP45 | c.1441C>T p.R481C | Missense Mutation (SNP) | VAF 24/134 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.193); catalogued as rs374155233, COSV59682046; called by muse, mutect2, varscan2
- VCPIP1 | c.1661C>G p.S554C | Missense Mutation (SNP) | VAF 89/638 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as COSV60049400; called by muse, mutect2, varscan2
- XIRP2 | c.2496A>C p.E832D (on ENST00000628543; = p.E1007D on NM_152381.6) | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54687255; called by muse, mutect2, varscan2
- ZFP42 | c.22C>T p.R8W | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.133); catalogued as COSV58818502; called by muse, mutect2, varscan2
- ZNF354C | c.1314A>C p.K438N | Missense Mutation (SNP) | VAF 37/179 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59609305; called by muse, mutect2, varscan2
- ZNF518A | c.2010C>A p.S670R | Missense Mutation (SNP) | VAF 39/247 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.282); catalogued as COSV60152548; called by muse, mutect2, varscan2
- ZNF676 | c.326A>T p.E109V (on ENST00000650058; = p.E77V on NM_001001411.3) | Missense Mutation (SNP) | VAF 36/156 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV68092175, COSV68092885; called by muse, mutect2, varscan2
- ZP4 | c.323G>T p.G108V | Missense Mutation (SNP) | VAF 294/502 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV63912997; called by muse, mutect2, varscan2
- CDH20 | c.2258A>G p.D753G | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.065); called by muse, mutect2
- CHD3 | c.655G>T p.A219S | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated, low confidence (0.25); PolyPhen probably damaging (0.978); called by muse, varscan2
- TRAV9-2 | c.91A>T p.T31S | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- ADAM15 | c.378T>C p.Y126= | Silent (SNP) | VAF 73/289 reads (25%) | catalogued as COSV55061752; called by muse, mutect2, varscan2
- ADCY4 | c.1446G>T p.L482= | Silent (SNP) | VAF 16/71 reads (23%) | catalogued as COSV60256396; called by muse, mutect2, varscan2
- CD40LG | c.315G>A p.T105= | Silent (SNP) | VAF 27/171 reads (16%) | catalogued as rs778398894, COSV65698875; called by muse, mutect2, varscan2
- CETN1 | c.474C>T p.N158= | Silent (SNP) | VAF 14/50 reads (28%) | catalogued as COSV59121733; called by muse, mutect2, varscan2
- DHCR24 | c.309T>A p.R103= | Silent (SNP) | VAF 64/207 reads (31%) | catalogued as COSV64875234; called by muse, mutect2, varscan2
- ERMP1 | c.1830C>T p.L610= | Silent (SNP) | VAF 12/83 reads (14%) | catalogued as rs754533913, COSV53038627; called by muse, mutect2, varscan2
- GATA3 | c.537C>T p.D179= | Silent (SNP) | VAF 11/68 reads (16%) | catalogued as rs987472805, COSV60521173, COSV99062030; called by muse, mutect2, varscan2
- GPRC5A | c.609C>T p.F203= | Silent (SNP) | VAF 9/193 reads (5%) | catalogued as COSV50008370; called by muse, mutect2
- GRIN2A | c.3505C>A p.R1169= | Silent (SNP) | VAF 173/340 reads (51%) | catalogued as COSV58036726, COSV58048965; called by muse, mutect2, varscan2
- HIP1R | c.1950T>C p.C650= | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as rs762541557, COSV53443543; called by muse, mutect2, varscan2
- L3MBTL1 | c.2190C>T p.V730= (on ENST00000418998 / NM_001377303.1; = p.V640= on NM_015478.7) | Silent (SNP) | VAF 10/65 reads (15%) | catalogued as rs374857830; called by muse, mutect2, varscan2
- LAMC2 | c.2997C>T p.S999= | Silent (SNP) | VAF 41/177 reads (23%) | catalogued as rs188628612, COSV99917684; ClinVar: likely benign; called by muse, mutect2, varscan2
- LGMN | c.645G>T p.S215= | Silent (SNP) | VAF 26/168 reads (15%) | catalogued as COSV58402853, COSV58404575; called by muse, mutect2, varscan2
- MRGPRX4 | c.186C>T p.S62= | Silent (SNP) | VAF 39/130 reads (30%) | catalogued as rs754405552, COSV100049872, COSV58591257; called by muse, mutect2, varscan2
- OR5AP2 | c.183C>A p.L61= | Silent (SNP) | VAF 44/85 reads (52%) | catalogued as COSV57258256, COSV57258965; called by muse, mutect2, varscan2
- ROR2 | c.405C>T p.C135= | Silent (SNP) | VAF 25/106 reads (24%) | catalogued as rs776789257, COSV65216331, COSV65219078; called by muse, varscan2
- SLC26A8 | c.2373C>T p.A791= | Silent (SNP) | VAF 67/132 reads (51%) | catalogued as rs376957512; called by muse, mutect2, varscan2
- TSHZ2 | c.1971G>A p.L657= | Silent (SNP) | VAF 325/1746 reads (19%) | catalogued as COSV61590277; called by muse, mutect2, varscan2
- TSHZ2 | c.2226G>A p.L742= | Silent (SNP) | VAF 347/1786 reads (19%) | catalogued as COSV61590281; called by muse, mutect2, varscan2
- TSLP | c.33A>T p.S11= | Silent (SNP) | VAF 84/209 reads (40%) | catalogued as COSV61292153; called by muse, mutect2, varscan2
- XKR4 | c.45C>T p.S15= | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as rs1403261466, COSV59331262; called by muse, mutect2, varscan2
- ZC4H2 | c.*1A>G | 3'UTR (SNP) | VAF 9/55 reads (16%) | called by muse, mutect2, varscan2
